Somatic mutation profile of tumor specimen TCGA-4Z-AA84-01A (aliquot TCGA-4Z-AA84-01A-11D-A391-08) from TCGA case TCGA-4Z-AA84, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 61.3 years (22,397 days).
Specimen TCGA-4Z-AA84-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6178579c-61a0-4bfd-b0f3-12ee2cc73308.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4Z-AA84-10A (Blood Derived Normal), aliquot TCGA-4Z-AA84-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd54b332-95b3-4e1e-b16b-7459224318bb

The open-access MAF lists 583 somatic variants for this specimen: 390 protein-altering or splice-affecting, 175 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 336, Silent 175, Nonsense Mutation 24, Intron 9, In Frame Del 8, Frame Shift Del 7, Frame Shift Ins 6, Splice Site 5, Splice Region 4, 5'UTR 3, RNA 3, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.4396C>T p.R1466* | Nonsense Mutation (SNP) | VAF 61/150 reads (41%) | hotspot (GDC flag); catalogued as rs730881369, CM990210, COSV53723637, COSV99589850; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERCC2 | c.215A>G p.Y72C | Missense Mutation (SNP) | VAF 32/145 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55538855, COSV99676553; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 16/23 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.6992C>T p.S2331L (on ENST00000272895 / NM_173076.3; = p.S2013L on NM_015657.3) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.779); catalogued as COSV55955292; called by muse, mutect2, varscan2
- ABCA8 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV52207907; called by muse, mutect2, varscan2
- ABHD15 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1438770098, COSV56196179; called by muse, mutect2, varscan2
- AC008397.2 | c.19G>A p.G7S | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs1283809646, COSV100828294; called by muse, varscan2
- AC244197.3 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 61/100 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM990748, COSV61713503; called by muse, mutect2, varscan2
- ACAN | c.855G>T p.Q285H | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV61365725; called by muse, mutect2, varscan2
- ACLY | c.995A>T p.H332L | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV61251958; called by muse, mutect2, varscan2
- ACP3 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as COSV60485450; called by muse, mutect2, varscan2
- ACY3 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99663019; called by muse, mutect2
- ADAD1 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV56645696; called by muse, mutect2, varscan2
- ADAM19 | c.657T>A p.D219E | Missense Mutation (SNP) | VAF 101/192 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57435334; called by muse, mutect2, varscan2
- ADAMTS15 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs748357097, COSV54508201; called by muse, mutect2, varscan2
- ADAT1 | c.740C>A p.A247D | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV57187773; called by muse, mutect2, varscan2
- ADCY8 | c.1798G>C p.D600H | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.88); catalogued as COSV53896579, COSV53904452, COSV53918783; called by muse, mutect2, varscan2
- ADGRG4 | c.9036T>C p.S3012= | Splice Region (SNP) | VAF 11/19 reads (58%) | catalogued as rs756965146, COSV54962640; called by muse, mutect2
- ALDH1A2 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51087136, COSV99990775; called by muse, mutect2, varscan2
- ALPK3 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51936910; called by muse, mutect2, varscan2
- AMBN | c.15G>C p.K5N | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV100534385, COSV59827430; called by muse, mutect2, varscan2
- AMIGO2 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); catalogued as COSV56975074; called by muse, mutect2, varscan2
- AMOT | c.1978C>G p.L660V (on ENST00000371959 / NM_001113490.1; = p.L251V on NM_133265.3) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV59066404; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3832G>A p.D1278N | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV51854095; called by muse, mutect2, varscan2
- ANKLE2 | c.2297G>A p.R766K | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.155); catalogued as COSV61710777; called by muse, mutect2, varscan2
- ANKRA2 | c.119C>A p.S40* | Nonsense Mutation (SNP) | VAF 53/166 reads (32%) | catalogued as COSV99707033; called by muse, mutect2, varscan2
- ANO8 | c.2797G>A p.E933K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs779276632, COSV50191142; called by muse, mutect2, varscan2
- AP3B1 | c.1870C>T p.H624Y | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99671650; called by muse, mutect2
- APOA5 | c.1057C>T p.H353Y | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1164371033, COSV57062065, COSV57064138; called by muse, mutect2, varscan2
- APOBR | c.2438G>A p.R813K (on ENST00000431282; = p.R822K on NM_018690.4) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV100112759, COSV60492612; called by muse, mutect2, varscan2
- ARHGEF15 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV62725020, COSV62725217; called by muse, mutect2, varscan2
- ARHGEF17 | c.5955C>A p.F1985L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs1407636125, COSV55235404; called by muse, mutect2, varscan2
- ARHGEF28 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.895); catalogued as rs769069681, COSV55246515, COSV55264183; called by muse, mutect2
- ARHGEF9 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV53641702; called by muse, mutect2, varscan2
- ARID2 | c.1837C>T p.Q613* | Nonsense Mutation (SNP) | VAF 51/140 reads (36%) | catalogued as COSV57596554, COSV57617903; called by muse, mutect2, varscan2
- ARID5B | c.11A>C p.N4T | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV54426390; called by muse, mutect2, varscan2
- ARPC5 | c.316C>A p.L106I | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54172220; called by muse, mutect2, varscan2
- ASXL1 | c.3394G>A p.E1132K | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as COSV60115319; called by muse, mutect2, varscan2
- ATL2 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs1411611703, COSV60054608; called by muse, mutect2, varscan2
- ATN1 | c.1712C>T p.S571F | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV63110196, COSV63112331; called by muse, mutect2, varscan2
- BABAM2 | c.852-1G>A p.X284_splice | Splice Site (SNP) | VAF 19/77 reads (25%) | catalogued as COSV59629210, COSV59633893; called by muse, mutect2, varscan2
- BCL6B | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 87/134 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV53428881; called by muse, mutect2, varscan2
- BDP1 | c.6670G>T p.G2224C | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV62433068; called by muse, mutect2, varscan2
- BLZF1 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1457020953, COSV61394421; called by muse, mutect2, varscan2
- BPIFB4 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.306); catalogued as COSV100971539; called by muse, mutect2, varscan2
- BPTF | c.3686C>G p.S1229C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as COSV58843056; called by muse, mutect2, varscan2
- BSDC1 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.243); catalogued as rs1346513290, COSV61982716; called by muse, mutect2, varscan2
- C10orf90 | c.289C>T p.H97Y | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.321); catalogued as COSV52960074; called by muse, mutect2, varscan2
- C16orf86 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.136); catalogued as COSV99708217; called by muse, mutect2
- C20orf194 | c.597dup p.T200Yfs*5 | Frame Shift Ins (INS) | VAF 13/55 reads (24%) | catalogued as rs1221445330; called by mutect2, pindel, varscan2
- C8orf76 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 71/122 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374975138, COSV99414859; called by muse, mutect2, varscan2
- CACNA1A | c.5234G>A p.R1745Q | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.063); catalogued as rs770276164, COSV64205998; called by muse, mutect2, varscan2
- CACNA1F | c.3374C>T p.A1125V | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557107162, COSV59904236; called by muse, mutect2, varscan2
- CADM2 | c.704C>A p.T235N (on ENST00000407528 / NM_001167674.2; = p.T237N on NM_153184.4) | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV67391713; called by muse, mutect2, varscan2
- CAMTA2 | c.3533G>A p.R1178H | Missense Mutation (SNP) | VAF 56/85 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as COSV52778572; called by muse, mutect2, varscan2
- CATSPER3 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV50948218; called by muse, mutect2, varscan2
- CATSPERB | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV56431378, COSV99831581; called by muse, mutect2, varscan2
- CBY2 | c.190A>T p.N64Y | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV100137629; called by muse, mutect2
- CCDC183 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs200507112; called by muse, mutect2, varscan2
- CCDC50 | c.289A>G p.I97V | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as rs765407189, COSV66669034; called by muse, mutect2, varscan2
- CCDC88A | c.4592C>T p.A1531V (on ENST00000436346 / NM_001365480.1; = p.A1503V on NM_018084.5) | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as rs775263452, COSV55066799; called by muse, mutect2, varscan2
- CCDC88C | c.5956C>T p.P1986S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1354995495, COSV57797497; called by muse, mutect2, varscan2
- CCDC9B | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV66875402; called by muse, mutect2, varscan2
- CCT8L2 | c.1654dup p.I552Nfs*6 | Frame Shift Ins (INS) | VAF 16/86 reads (19%) | catalogued as rs780034402; called by mutect2, varscan2
- CD81 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.062); catalogued as COSV55133699; called by muse, mutect2, varscan2
- CDC42 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV59663041; called by muse, mutect2
- CDH11 | c.335C>A p.A112D | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51754297, COSV51768248; called by muse, mutect2, varscan2
- CDK13 | c.3757C>T p.R1253* | Nonsense Mutation (SNP) | VAF 31/105 reads (30%) | catalogued as rs1394355177, COSV99475602; called by muse, mutect2, varscan2
- CDKN2A | c.70C>G p.R24G | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.54); catalogued as rs761014328, COSV58707278; called by mutect2, varscan2
- CELSR3 | c.6567+1G>T p.X2189_splice | Splice Site (SNP) | VAF 4/21 reads (19%) | catalogued as COSV50958330; called by muse, mutect2, varscan2
- CELSR3 | c.5395C>T p.Q1799* | Nonsense Mutation (SNP) | VAF 6/61 reads (10%) | catalogued as COSV99373662; called by muse, mutect2, varscan2
- CENATAC | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV57722091; called by muse, mutect2, varscan2
- CEP350 | c.6104C>T p.S2035L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62607109; called by muse, mutect2, varscan2
- CES3 | c.953G>A p.G318D | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); catalogued as COSV57594041, COSV57594599; called by muse, mutect2
- CFAP20DC | c.2236C>T p.R746W (on ENST00000482387 / NM_001351530.2; = p.R495W on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as rs775320019, COSV55921364; called by muse, mutect2, varscan2
- CFAP91 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56343104; called by muse, mutect2, varscan2
- CHD5 | c.2194A>G p.T732A | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52420946; called by muse, mutect2, varscan2
- CHSY1 | c.1765G>A p.D589N | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.043); catalogued as COSV54255096; called by muse, mutect2, varscan2
- CLCN2 | c.1543G>A p.V515M | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs778519053, COSV55603079; called by muse, mutect2, varscan2
- CLEC17A | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 88/218 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as COSV100355390, COSV60428982; called by muse, mutect2, varscan2
- CMAS | c.961-1G>T p.X321_splice | Splice Site (SNP) | VAF 10/22 reads (45%) | catalogued as rs1195454421, COSV57557171; called by muse, mutect2, varscan2
- CMIP | c.2098G>A p.D700N (on ENST00000537098 / NM_198390.2; = p.D606N on NM_030629.3) | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1234305880, COSV101220914; called by muse, mutect2, varscan2
- CNN2 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as COSV54034066; called by muse, mutect2, varscan2
- CNNM4 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 132/202 reads (65%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV65660920; called by muse, mutect2, varscan2
- COL12A1 | c.7151A>C p.K2384T | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59402540; called by muse, mutect2
- COL20A1 | c.1358G>T p.G453V | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.858); catalogued as rs1485208492, COSV100490652; called by muse, mutect2
- COX5A | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV59279769; called by muse, mutect2, varscan2
- COX6C | c.67A>T p.M23L | Missense Mutation (SNP) | VAF 150/354 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV52553505, COSV52554400; called by muse, mutect2, varscan2
- CPSF1 | c.2873G>A p.R958Q | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs991875581, COSV100450475; called by muse, mutect2
- CPT1A | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as rs141191480; called by muse, mutect2, varscan2
- CREB3L2 | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV57798099; called by muse, mutect2, varscan2
- CRTC2 | c.1717C>G p.L573V | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as rs780162688, COSV57844791; called by muse, mutect2
- CSMD1 | c.4276G>A p.G1426R (on ENST00000520002; = p.G1425R on NM_033225.6) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59305929; called by muse, mutect2, varscan2
- CTNNB1 | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.553); catalogued as COSV62710579; called by muse, mutect2, varscan2
- CYC1 | c.804G>C p.K268N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59644783; called by muse, mutect2, varscan2
- CYP17A1 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.29); PolyPhen benign (0.425); catalogued as rs1438499447, COSV64005053; called by muse, mutect2, varscan2
- CYP1A2 | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.274); catalogued as COSV59660416; called by muse, mutect2, varscan2
- DCAF8 | c.67C>A p.P23T | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV58785157; called by muse, mutect2
- DDIAS | c.2695G>A p.E899K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV61272816; called by muse, mutect2, varscan2
- DDX17 | c.2015C>T p.S672L | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.098); catalogued as rs749066420, COSV53249067; called by muse, mutect2, varscan2
- DDX46 | c.2047C>G p.L683V | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62800298; called by muse, mutect2, varscan2
- DENND4C | c.1720T>G p.L574V | Missense Mutation (SNP) | VAF 89/138 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV66822916; called by muse, mutect2, varscan2
- DGCR6L | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1421616870, COSV99956859; called by muse, mutect2, varscan2
- DMP1 | c.1535G>T p.G512V | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56821502; called by muse, mutect2, varscan2
- DNAAF2 | c.2324T>A p.I775K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs1363447010, COSV53571122; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPH7 | c.376A>G p.K126E | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV53023204; called by muse, mutect2
- DSCAML1 | c.326C>A p.A109D (on ENST00000321322; = p.A49D on NM_020693.4) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58397875; called by muse, mutect2, varscan2
- DSEL | c.2870T>C p.L957P | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV59493499; called by muse, mutect2, varscan2
- DXO | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV61714543; called by muse, mutect2, varscan2
- E2F6 | c.242C>A p.S81Y | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV56216344; called by muse, mutect2, varscan2
- ECPAS | c.3346C>T p.Q1116* | Nonsense Mutation (SNP) | VAF 17/49 reads (35%) | catalogued as COSV99398396; called by muse, mutect2, varscan2
- EHD3 | c.170A>G p.N57S | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV59032136; called by muse, mutect2, varscan2
- EIF2B4 | c.1315G>A p.E439K (on ENST00000347454 / NM_001034116.2; = p.E438K on NM_015636.3) | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61457700; called by muse, mutect2, varscan2
- EIF4G3 | c.2792G>A p.R931H | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs745659570, COSV51676911; called by muse, mutect2, varscan2
- EPG5 | c.2003C>T p.S668L | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV56353447; called by muse, mutect2, varscan2
- ERC2 | c.1590G>A p.M530I | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs746216863, COSV55646106; called by muse, mutect2, varscan2
- ERN1 | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs1301193058, COSV101458451; called by muse, mutect2, varscan2
- EWSR1 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.305); catalogued as rs1389184933, COSV100131529; called by muse, mutect2
- EXPH5 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs537658233, COSV56205805; called by muse, mutect2, varscan2
- FAM120A | c.1960C>T p.Q654* | Nonsense Mutation (SNP) | VAF 27/122 reads (22%) | catalogued as COSV99465613; called by muse, mutect2, varscan2
- FAM83H | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs948210399, COSV66353643, COSV66354317; called by muse, mutect2, varscan2
- FASTK | c.122C>G p.S41C | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99879788; called by muse, mutect2, varscan2
- FAT4 | c.1187T>C p.V396A | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV67894716; called by muse, mutect2, varscan2
- FBXO28 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.95); catalogued as rs1445130203, COSV100837442; called by muse, mutect2, varscan2
- FBXO41 | c.875A>T p.H292L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1483352486, COSV99721281; called by muse, mutect2
- FCN1 | c.53T>G p.L18W | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV65662724; called by muse, mutect2, varscan2
- FHIT | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1418764214, COSV59313152; called by muse, mutect2, varscan2
- FITM1 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.403); catalogued as COSV52825141; called by muse, mutect2, varscan2
- FOXP1 | c.1033A>T p.M345L | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV59548955; called by muse, mutect2, varscan2
- FRY | c.6710G>C p.S2237T | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV66575151; called by muse, mutect2
- FUT4 | c.839T>C p.L280P | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV100708094; called by mutect2, varscan2
- GABPB2 | c.372C>G p.I124M | Missense Mutation (SNP) | VAF 95/131 reads (73%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as rs1379045952, COSV64461241; called by muse, mutect2, varscan2
- GASK1B | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.487); catalogued as COSV56710176; called by muse, mutect2, varscan2
- GCC1 | c.928C>G p.R310G | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV50001706; called by muse, mutect2, varscan2
- GLT8D1 | c.432_438del p.E145* | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | catalogued as COSV56478119; called by mutect2, pindel, varscan2
- GOLGB1 | c.5779A>T p.M1927L | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV61468684; called by muse, mutect2, varscan2
- GPC2 | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV52785910; called by muse, mutect2, varscan2
- GRAMD2B | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.047); catalogued as COSV53509123; called by muse, mutect2, varscan2
- GRIK5 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.108); catalogued as rs267605508, COSV53474340; called by muse, mutect2, varscan2
- GRN | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as COSV50008150; called by muse, mutect2, varscan2
- GTF3C3 | c.764G>A p.W255* | Nonsense Mutation (SNP) | VAF 5/47 reads (11%) | catalogued as COSV99826465, COSV99826734; called by muse, mutect2, varscan2
- HBP1 | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 67/212 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs762848519, COSV56018717; called by muse, mutect2, varscan2
- HBS1L | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.11); catalogued as COSV63202195; called by muse, mutect2, varscan2
- HELZ | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.119); catalogued as COSV62379862; called by muse, mutect2, varscan2
- HELZ | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); catalogued as rs1267152431, COSV62379867; called by muse, mutect2, varscan2
- HERC1 | c.4570G>A p.E1524K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.931); catalogued as COSV71249330; called by muse, mutect2, varscan2
- HFE | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.375); catalogued as rs1190491989, COSV58513720; called by muse, mutect2, varscan2
- HIC2 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV68042641; called by muse, mutect2, varscan2
- HMGXB4 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as rs777204741, COSV53335236; called by muse, mutect2, varscan2
- HNRNPA3 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV66820802; called by muse, mutect2, varscan2
- HOXD11 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50912300; called by muse, mutect2, varscan2
- IGF1R | c.2620G>A p.E874K | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV51335034; called by muse, mutect2, varscan2
- IHO1 | c.877A>G p.K293E | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56509140; called by muse, mutect2, varscan2
- IL10RB | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51615636; called by muse, mutect2, varscan2
- IL12A | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.088); catalogued as rs1421706208, COSV59759783; called by muse, mutect2, varscan2
- IL18BP | c.234G>A p.L78= | Splice Region (SNP) | VAF 4/17 reads (24%) | catalogued as COSV52622003; called by muse, mutect2, varscan2
- IL1RAPL2 | c.738G>T p.M246I | Missense Mutation (SNP) | VAF 44/67 reads (66%) | SIFT tolerated (0.41); PolyPhen benign (0.023); catalogued as rs1343825151, COSV61170519, COSV61171045; called by muse, mutect2, varscan2
- IL21 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.009); catalogued as COSV52646632; called by muse, mutect2, varscan2
- INSM1 | c.1459C>T p.H487Y | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV59605140; called by muse, mutect2, varscan2
- IPCEF1 | c.355T>C p.Y119H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs920388495, COSV54548051; called by muse, mutect2, varscan2
- IQGAP1 | c.3253C>T p.L1085F | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV51588846; called by muse, mutect2, varscan2
- ITIH2 | c.2330C>G p.T777S | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.97); catalogued as COSV64434365; called by muse, mutect2, varscan2
- JCAD | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs563388639, COSV64758456; called by muse, mutect2, varscan2
- JHY | c.2231G>T p.G744V | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.226); catalogued as COSV57075633, COSV57078015; called by muse, mutect2, varscan2
- JMJD1C | c.3641A>G p.H1214R | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as rs775829102, COSV59516992; called by muse, mutect2
- KAT7 | c.1312G>A p.V438M | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52014360, COSV52015899; called by muse, mutect2, varscan2
- KCNH8 | c.1440G>A p.W480* | Nonsense Mutation (SNP) | VAF 26/89 reads (29%) | catalogued as COSV100109984; called by muse, mutect2, varscan2
- KCNN2 | c.683C>T p.P228L (on ENST00000264773; = p.P440L on NM_021614.4) | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1247869523, COSV53294847; called by muse, mutect2, varscan2
- KCNQ5 | c.2014A>G p.N672D | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.053); catalogued as COSV59673572; called by muse, mutect2, varscan2
- KCTD11 | c.722G>A p.R241Q (on ENST00000333751 / NM_001363642.1; = p.R202Q on NM_001002914.2) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV50138565; called by muse, mutect2, varscan2
- KDM2B | c.3830-1G>A p.X1277_splice | Splice Site (SNP) | VAF 14/90 reads (16%) | catalogued as COSV65643374; called by muse, mutect2, varscan2
- KDM6A | c.1624C>T p.Q542* | Nonsense Mutation (SNP) | VAF 15/29 reads (52%) | catalogued as COSV65037931; called by muse, mutect2, varscan2
- KIAA2026 | c.503G>T p.C168F | Missense Mutation (SNP) | VAF 54/87 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV52390732; called by muse, mutect2, varscan2
- KIF18B | c.1511C>T p.S504F (on ENST00000593135 / NM_001265577.2; = p.S516F on NM_001264573.2) | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs935381747, COSV59275127; called by muse, mutect2, varscan2
- KIF27 | c.4051C>T p.H1351Y | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.139); catalogued as COSV52829962; called by muse, mutect2, varscan2
- KMT2D | c.15994A>G p.M5332V | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.708); catalogued as rs763696810, COSV56468025; called by muse, mutect2, varscan2
- KPNA6 | c.248G>T p.R83I | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV65361378; called by muse, mutect2, varscan2
- KPRP | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.189); catalogued as COSV64222451; called by muse, mutect2, varscan2
- KRT24 | c.56G>A p.R19K | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV52881214; called by muse, mutect2, varscan2
- KRT71 | c.404A>G p.K135R | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV57292152; called by muse, mutect2, varscan2
- KRT82 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as rs909034934, COSV57786749; called by muse, mutect2, varscan2
- KSR1 | c.1250G>A p.R417K (on ENST00000644974 / NM_001367810.1; = p.R280K on NM_014238.2) | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as COSV52036509; called by muse, mutect2, varscan2
- LAMA2 | c.1693C>T p.Q565* | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | catalogued as COSV101370505; called by muse, mutect2, varscan2
- LAS1L | c.325G>C p.D109H | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.635); catalogued as COSV56708380; called by muse, mutect2, varscan2
- LCA5 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 80/181 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV63972339; called by muse, mutect2, varscan2
- LECT2 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV50847453; called by muse, mutect2, varscan2
- LETMD1 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as rs759163931, COSV50398674, COSV50399987; called by muse, mutect2
- LHX3 | c.575C>T p.S192F (on ENST00000371748 / NM_178138.6; = p.S197F on NM_014564.5) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs769868614, COSV100871210, COSV65583677; called by muse, mutect2, varscan2
- LIMK2 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV59183548; called by muse, mutect2, varscan2
- LPO | c.1611G>C p.K537N | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as COSV51861106; called by muse, mutect2, varscan2
- LRRC49 | c.1987G>A p.D663N | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs1214853791, COSV53013358; called by muse, mutect2, varscan2
- LRRK1 | c.5188T>C p.Y1730H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as COSV52621597; called by muse, mutect2, varscan2
- LY75-CD302 | c.5323A>G p.K1775E | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.366); catalogued as COSV52034042; called by muse, mutect2, varscan2
- MACC1 | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV60545032; called by muse, mutect2, varscan2
- MACF1 | c.4093C>T p.Q1365* | Nonsense Mutation (SNP) | VAF 8/82 reads (10%) | catalogued as COSV100484744; called by muse, mutect2
- MAGEB6B | c.1115T>C p.V372A | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as COSV69689797; called by muse, mutect2, varscan2
- MAP3K6 | c.3524G>A p.R1175Q | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as COSV58873530; called by muse, mutect2, varscan2
- MED9 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.681); catalogued as COSV51958075; called by muse, mutect2, varscan2
- MET | c.4054G>T p.V1352L | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT tolerated (1); PolyPhen possibly damaging (0.893); catalogued as COSV59265665; called by muse, mutect2, varscan2
- MTF1 | c.1896T>G p.C632W | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65990001; called by muse, mutect2, varscan2
- MTFR1 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.462); catalogued as rs371451393; called by muse, mutect2, varscan2
- MTR | c.762C>T p.L254= | Splice Region (SNP) | VAF 61/89 reads (69%) | catalogued as COSV63969047; called by muse, mutect2, varscan2
- MUC5B | c.1347C>G p.Y449* | Nonsense Mutation (SNP) | VAF 20/119 reads (17%) | catalogued as COSV101500388; called by muse, mutect2, varscan2
- MYOF | c.1844C>T p.S615L | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63704860; called by muse, mutect2, varscan2
- MYORG | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs1391713161, COSV99898648; called by muse, mutect2, varscan2
- NAA15 | c.1151A>G p.Y384C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56721461; called by muse, mutect2, varscan2
- NAV1 | c.3967G>T p.D1323Y | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55222404; called by muse, mutect2, varscan2
- NCOA1 | c.343C>G p.L115V | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV56049846; called by muse, mutect2, varscan2
- NDUFB4 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV51741759; called by muse, mutect2
- NEK8 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as rs756755633, COSV52047319; called by muse, mutect2
- NF1 | c.3028C>T p.Q1010* | Nonsense Mutation (SNP) | VAF 20/32 reads (63%) | catalogued as COSV62208659; called by muse, varscan2
- NHLRC3 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV65463272; called by muse, mutect2
- NNAT | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.638); catalogued as COSV50350689, COSV50351729; called by muse, mutect2, varscan2
- NOS1AP | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62638107; called by muse, mutect2, varscan2
- NRCAM | c.3521T>C p.M1174T (on ENST00000379028 / NM_001371124.1; = p.M1053T on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV61043977; called by muse, mutect2, varscan2
- NRG1 | c.700A>T p.K234* | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | catalogued as rs765565065, COSV55172696, COSV99828496, COSV99828925; called by muse, mutect2, varscan2
- OAZ1 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.226); catalogued as COSV59233392; called by muse, mutect2, varscan2
- OBSCN | c.3167C>T p.A1056V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.927); catalogued as rs926490517, COSV52804997; called by muse, mutect2, varscan2
- OR10T2 | c.713T>A p.F238Y | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57782519; called by muse, mutect2, varscan2
- OR14J1 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV65845869; called by muse, mutect2, varscan2
- OR4N2 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.137); catalogued as COSV60052743, COSV60053213; called by muse, mutect2, varscan2
- OR5D16 | c.879T>A p.S293R | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65722529; called by muse, mutect2, varscan2
- OR6A2 | c.866T>C p.L289S | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.602); catalogued as COSV60265492; called by muse, mutect2, varscan2
- OTOGL | c.5222T>C p.I1741T (on ENST00000547103; = p.I1732T on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1030322134, COSV54020535; called by muse, mutect2, varscan2
- OTOP2 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 32/41 reads (78%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as rs767276003, COSV58882604; called by muse, mutect2, varscan2
- P4HA1 | c.89A>G p.D30G | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.869); catalogued as COSV54963866; called by muse, mutect2, varscan2
- PAN2 | c.1172A>T p.D391V | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV57755206; called by muse, mutect2, varscan2
- PARP10 | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.445); catalogued as rs782705803, COSV57299045; called by muse, mutect2, varscan2
- PATJ | c.22+1G>A p.X8_splice | Splice Site (SNP) | VAF 77/119 reads (65%) | catalogued as COSV57167637; called by muse, mutect2, varscan2
- PAX9 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs375546483, COSV64062118; called by muse, mutect2, varscan2
- PBX2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.358); catalogued as rs773626213, COSV66708712; called by muse, mutect2, varscan2
- PCDH9 | c.2656A>G p.T886A | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV60573460; called by muse, mutect2, varscan2
- PCDHA9 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.94); catalogued as COSV65329972; called by muse, mutect2, varscan2
- PCNT | c.2353A>G p.I785V | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as rs772309220, COSV64031087; called by muse, mutect2, varscan2
- PDGFRB | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.021); catalogued as COSV55808200; called by muse, mutect2, varscan2
- PEF1 | c.10T>C p.Y4H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs140479455; called by muse, mutect2
- PEG3 | c.2170C>T p.H724Y | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as rs776237105, COSV55631472; called by muse, mutect2, varscan2
- PIK3CA | c.2254C>G p.L752V | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV55961419; called by muse, mutect2, varscan2
- PKN2 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV60133449; called by muse, mutect2, varscan2
- PLAGL2 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV55789137; called by muse, mutect2, varscan2
- PLCH2 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs1221516458, COSV53946971; called by muse, mutect2, varscan2
- PLD1 | c.2897A>G p.Y966C | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV60571691; called by muse, mutect2, varscan2
- PLEKHA6 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV55331056, COSV55334020; called by muse, mutect2, varscan2
- PLEKHG4 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.452); catalogued as COSV100430978; called by muse, mutect2
- PNPLA1 | c.1142C>T p.P381L (on ENST00000394571 / NM_001374623.1; = p.P286L on NM_173676.2) | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV57236471; called by muse, mutect2
- POLA2 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as COSV55484940; called by muse, mutect2, varscan2
- POLR1A | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54481781; called by muse, mutect2, varscan2
- POLR2H | c.443T>C p.L148P | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV52616668; called by muse, mutect2, varscan2
- POLR3B | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 39/228 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.125); catalogued as COSV57282344; called by muse, mutect2, varscan2
- PPARG | c.746C>T p.S249L (on ENST00000287820 / NM_015869.5; = p.S219L on NM_005037.7) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as CM1412199, COSV55143511; called by muse, mutect2, varscan2
- PPFIA3 | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV61953557; called by muse, mutect2, varscan2
- PPFIA3 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.769); catalogued as COSV61953564; called by muse, mutect2, varscan2
- PPM1A | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); catalogued as COSV57787909; called by muse, mutect2, varscan2
- PPP2R5A | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 42/69 reads (61%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); catalogued as rs755132136, COSV54788941, COSV54789518; called by muse, mutect2, varscan2
- PREX2 | c.2030C>T p.T677I | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as rs765627262, COSV55788816; called by muse, mutect2, varscan2
- PRG2 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs369365761; called by muse, mutect2, varscan2
- PRRC2A | c.5072C>T p.S1691L | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs770566834, COSV52993398; called by muse, mutect2, varscan2
- PRSS36 | c.1016A>T p.Q339L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as COSV51638773; called by muse, mutect2, varscan2
- PSMD3 | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV52858923, COSV52858944; called by muse, mutect2, varscan2
- PTPRE | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs775207835, COSV54555774; called by muse, mutect2, varscan2
- PTPRF | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as COSV63444257; called by muse, mutect2, varscan2
- PTPRR | c.1079C>G p.P360R | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.05); catalogued as COSV51740796; called by muse, mutect2, varscan2
- PZP | c.1147T>C p.S383P | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.514); catalogued as COSV54366209; called by muse, mutect2, varscan2
- RAB3B | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.491); catalogued as rs779381327, COSV63228342; called by muse, mutect2, varscan2
- RALGAPA1 | c.1702A>C p.M568L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV99354937; called by muse, mutect2
- RASAL2 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV62718907; called by muse, mutect2, varscan2
- RASGRP1 | c.1093C>A p.L365M | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs1247742652, COSV60366630; called by muse, mutect2, varscan2
- RELL2 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV51837074; called by muse, mutect2
- RHBDF2 | c.1490C>T p.S497L | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV51685643; called by muse, mutect2, varscan2
- RIMKLB | c.174G>A p.L58= | Splice Region (SNP) | VAF 3/31 reads (10%) | catalogued as COSV100223919; called by muse, mutect2
- RIPK3 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.671); catalogued as rs1465184165, COSV53476555; called by muse, mutect2, varscan2
- RNF175 | c.219G>A p.W73* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as rs771987548, COSV99924103; called by muse, varscan2
- RPGRIP1 | c.3515A>G p.H1172R | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as COSV52854006; called by muse, mutect2, varscan2
- RPS4Y1 | c.443G>C p.R148P | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV51711188; called by muse, mutect2, varscan2
- RRP1B | c.1483G>C p.E495Q | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV61479772; called by muse, mutect2, varscan2
- RUVBL1 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100494234, COSV59475801; called by muse, mutect2, varscan2
- SAXO1 | c.509G>A p.R170K | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.932); catalogued as rs139778740, COSV101000184; called by muse, mutect2, varscan2
- SBSPON | c.162A>C p.Q54H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV52077377; called by muse, mutect2, varscan2
- SCAF11 | c.1154T>C p.L385S | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.086); catalogued as COSV65478106; called by muse, mutect2, varscan2
- SCAI | c.411T>A p.Y137* (on ENST00000336505 / NM_001144877.3; = p.Y160* on NM_173690.5) | Nonsense Mutation (SNP) | VAF 27/91 reads (30%) | catalogued as COSV100332663; called by muse, mutect2, varscan2
- SCN11A | c.4923C>G p.I1641M | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV56574592; called by muse, varscan2
- SEC24B | c.3761C>T p.S1254F | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54503637; called by muse, mutect2, varscan2
- SETD2 | c.3311A>G p.E1104G | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV57445432; called by muse, mutect2, varscan2
- SGMS1 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV62371664; called by muse, mutect2, varscan2
- SH3RF1 | c.38C>G p.P13R | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52923350, COSV99499380; called by muse, mutect2, varscan2
- SLC16A5 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.029); catalogued as COSV55461109; called by muse, mutect2, varscan2
- SLC23A2 | c.476_477del p.G159Vfs*25 | Frame Shift Del (DEL) | VAF 86/277 reads (31%) | catalogued as COSV57777315; called by mutect2, pindel, varscan2
- SLC30A9 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.034); catalogued as rs1371027337, COSV52557912; called by muse, mutect2, varscan2
- SLC36A1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as COSV54655462; called by muse, mutect2, varscan2
- SLC38A10 | c.45C>G p.I15M | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV55846576; called by muse, varscan2
- SLCO1C1 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs759255086, COSV56873956; called by muse, mutect2, varscan2
- SMARCA1 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 49/76 reads (64%) | catalogued as COSV64410923, COSV64413608; called by muse, mutect2, varscan2
- SMARCC2 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.899); catalogued as rs1246480328, COSV57222040; called by muse, varscan2
- SMC5 | c.2630C>T p.S877L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.834); catalogued as COSV63194597; called by muse, mutect2, varscan2
- SNCA | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV61135870; called by muse, mutect2, varscan2
- SNX31 | c.1238A>G p.Y413C | Missense Mutation (SNP) | VAF 68/133 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV61264243; called by muse, mutect2, varscan2
- SORBS2 | c.860C>T p.S287L (on ENST00000284776 / NM_021069.5; = p.S380L on NM_003603.6) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.05); catalogued as COSV53004774; called by muse, mutect2, varscan2
- SORBS2 | c.406C>T p.Q136* (on ENST00000284776 / NM_021069.5; = p.Q182* on NM_003603.6) | Nonsense Mutation (SNP) | VAF 21/50 reads (42%) | catalogued as COSV99511182; called by muse, mutect2, varscan2
- SP4 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1413201879, COSV56024526; called by muse, mutect2, varscan2
- SPAG1 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs764448315, COSV52561709; called by muse, mutect2, varscan2
- SPAG17 | c.1837G>A p.D613N | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as rs759187136, COSV60464075; called by muse, mutect2
- SPG11 | c.3076G>A p.E1026K | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.061); catalogued as COSV55999505; called by muse, mutect2, varscan2
- SPRR2D | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 59/93 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs973297458, COSV64209366; called by muse, mutect2, varscan2
- SPRY4 | c.82C>T p.H28Y (on ENST00000434127 / NM_001127496.3; = p.H51Y on NM_030964.4) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100702229, COSV59986483; called by muse, mutect2, varscan2
- SPTSSA | c.197A>G p.Y66C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1175878157, COSV53295041; called by muse, mutect2, varscan2
- SRF | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV54839441; called by muse, mutect2, varscan2
- SRRM1 | c.1582A>G p.S528G | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV60479364; called by muse, mutect2
- SRRT | c.230A>G p.Q77R | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.122); catalogued as rs1318130226, COSV61453814; called by muse, mutect2, varscan2
- ST7 | c.1381C>A p.L461I (on ENST00000265437 / NM_021908.3; = p.L438I on NM_018412.4) | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55389631; called by muse, mutect2, varscan2
- STAG2 | c.2297G>A p.R766K | Missense Mutation (SNP) | VAF 71/112 reads (63%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV54360424, COSV54366811; called by muse, mutect2, varscan2
- STXBP1 | c.560C>A p.P187Q | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64814620; called by muse, mutect2, varscan2
- STXBP5L | c.1787C>G p.T596S | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.077); catalogued as COSV56525663; called by muse, mutect2, varscan2
- SURF6 | c.64T>G p.S22A | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV59299214; called by muse, mutect2, varscan2
- SVEP1 | c.1367T>C p.M456T | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV57042870; called by muse, mutect2, varscan2
- SYNE1 | c.18771G>C p.E6257D (on ENST00000367255 / NM_182961.4; = p.E6186D on NM_033071.3) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); catalogued as COSV55050443, COSV99550735; called by muse, mutect2, varscan2
- TAF1D | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV58681539; called by muse, mutect2, varscan2
- TANC2 | c.1483G>T p.E495* | Nonsense Mutation (SNP) | VAF 30/95 reads (32%) | catalogued as COSV101267460, COSV67337125; called by muse, mutect2, varscan2
- TBK1 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.956); catalogued as rs1417127657, COSV59157388; called by muse, mutect2, varscan2
- TBRG4 | c.1196C>T p.S399L | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV51833831; called by muse, mutect2, varscan2
- TBX19 | c.1230G>T p.E410D | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV63198132; called by muse, mutect2, varscan2
- TBX3 | c.15G>A p.M5I | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV57473950; called by muse, mutect2, varscan2
- TCF21 | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 11/86 reads (13%) | catalogued as COSV52819754; called by muse, mutect2, varscan2
- TCHH | c.5234G>A p.R1745H | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.049); catalogued as rs1425330978, COSV64276511; called by muse, mutect2
- TCHH | c.3974G>C p.R1325T | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV64275836; called by muse, mutect2
- TDRD7 | c.1860C>G p.Y620* | Nonsense Mutation (SNP) | VAF 42/117 reads (36%) | catalogued as COSV100795658, COSV62429308; called by muse, mutect2, varscan2
- TERF2IP | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as rs1411298129, COSV55613453; called by muse, mutect2, varscan2
- TEX45 | c.941T>G p.L314R | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV64463881; called by muse, varscan2
- THSD7A | c.453A>T p.E151D | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV70269296; called by muse, mutect2
- TMED7 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56695907; called by muse, mutect2, varscan2
- TMEM132B | c.2461G>A p.E821K | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.8); PolyPhen benign (0.09); catalogued as rs919773875, COSV54762508; called by muse, mutect2, varscan2
- TNKS | c.1822C>G p.R608G | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV60063466; called by muse, mutect2, varscan2
- TNPO3 | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as rs1158559409, COSV55284673; called by muse, mutect2, varscan2
- TOR1AIP2 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.076); catalogued as COSV62626075; called by muse, mutect2, varscan2
- TOR3A | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1188151792, COSV100751331; called by muse, mutect2, varscan2
- TRAM2 | c.375C>A p.F125L | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51734041; called by muse, mutect2, varscan2
- TRIB2 | c.112A>G p.S38G | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV50228063; called by muse, mutect2, varscan2
- TRIM24 | c.1020G>A p.M340I | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV58975746; called by muse, mutect2, varscan2
- TRIM73 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as COSV51903924; called by muse, mutect2, varscan2
- TSC22D1 | c.370A>G p.S124G | Missense Mutation (SNP) | VAF 112/170 reads (66%) | SIFT deleterious (0.05); PolyPhen benign (0.433); catalogued as COSV71776043; called by muse, mutect2, varscan2
- TTL | c.556C>T p.L186F | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV51975746; called by muse, mutect2, varscan2
- UBXN2B | c.754G>T p.D252Y | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV68308507, COSV68309413; called by muse, mutect2, varscan2
- UNCX | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100310303, COSV60332803, COSV60332865; called by muse, mutect2, varscan2
- USP4 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV55539136, COSV99649742; called by muse, mutect2
- USPL1 | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 33/143 reads (23%) | catalogued as COSV99687315; called by muse, mutect2, varscan2
- UTRN | c.4101G>T p.R1367S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62342414; called by muse, mutect2, varscan2
- VCPIP1 | c.1777C>A p.P593T | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV60049307; called by muse, mutect2, varscan2
- WDR36 | c.2633A>C p.K878T | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as COSV72605381; called by muse, mutect2, varscan2
- XPO5 | c.2725G>A p.E909K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.253); catalogued as COSV54833062; called by muse, mutect2, varscan2
- XRCC2 | c.710A>G p.H237R | Missense Mutation (SNP) | VAF 78/163 reads (48%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.747); catalogued as COSV63770863; called by muse, mutect2, varscan2
- YIPF4 | c.467G>C p.R156T | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53214388, COSV53214693; called by muse, mutect2, varscan2
- YWHAE | c.455A>G p.Y152C | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV51984146; called by mutect2, varscan2
- ZBED9 | c.2342A>G p.Y781C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.339); catalogued as rs747825138, COSV71729646; called by muse, mutect2, varscan2
- ZBTB1 | c.1826A>G p.Q609R | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV62439300; called by muse, mutect2, varscan2
- ZBTB34 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as COSV59860467; called by muse, mutect2, varscan2
- ZFAND2B | c.190G>C p.V64L | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV54698574; called by muse, mutect2, varscan2
- ZFP37 | c.1379C>G p.P460R | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1179096420, COSV65287058, COSV65287988, COSV65288866; called by muse, mutect2, varscan2
- ZNF148 | c.1181A>G p.K394R | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1330204508, COSV62306431; called by muse, mutect2, varscan2
- ZNF148 | c.704G>A p.R235K | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV62306442; called by muse, mutect2, varscan2
- ZNF286A | c.1537C>T p.Q513* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV101224796; called by muse, mutect2, varscan2
- ZNF365 | c.539T>C p.I180T | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs548450137, COSV67926029; called by muse, mutect2, varscan2
- ZNF44 | c.172G>A p.A58T (on ENST00000356109 / NM_001164276.2; = p.A10T on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/223 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.097); catalogued as rs1319800154, COSV61135925; called by muse, mutect2, varscan2
- ZNF451 | c.119G>C p.R40P | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100674825, COSV62598909; called by muse, mutect2, varscan2
- ZNF483 | c.1802A>G p.H601R | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58516582; called by muse, mutect2, varscan2
- ZNF486 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.246); catalogued as COSV58721104; called by muse, mutect2, varscan2
- ZNF572 | c.767G>A p.S256N | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.496); catalogued as COSV60002457; called by muse, mutect2, varscan2
- ZNF626 | c.191C>T p.T64I | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV52480071, COSV52482125; called by muse, mutect2, varscan2
- ZNF781 | c.774T>A p.N258K | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as rs139260207; called by muse, mutect2
- ZNF781 | c.172G>T p.G58W | Missense Mutation (SNP) | VAF 207/345 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62202329; called by muse, mutect2, varscan2
- ZNF829 | c.1216A>C p.K406Q | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV66986697; called by muse, mutect2
- ZNFX1 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV65576650, COSV65577235; called by muse, mutect2, varscan2
- ARID1A | c.2749_2752dup p.M918Kfs*19 | Frame Shift Ins (INS) | VAF 27/60 reads (45%) | called by mutect2, pindel, varscan2
- ATP1B4 | c.229_252del p.P77_Q84del | In Frame Del (DEL) | VAF 12/22 reads (55%) | called by mutect2, pindel
- BIRC6 | c.11077_11090del p.V3693Yfs*10 | Frame Shift Del (DEL) | VAF 12/45 reads (27%) | called by mutect2, pindel, varscan2
- BLK | c.433_437dup p.S147Pfs*20 | Frame Shift Ins (INS) | VAF 12/65 reads (18%) | called by mutect2, pindel, varscan2
- CDH17 | c.1235_1243del p.K412_D414del | In Frame Del (DEL) | VAF 54/158 reads (34%) | called by mutect2, pindel, varscan2
- CHRNA6 | c.920_942del p.L307Hfs*54 | Frame Shift Del (DEL) | VAF 20/84 reads (24%) | called by mutect2, pindel
- FAM72C | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FCGBP | c.6493G>A p.D2165N | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.29); called by muse, mutect2
- GUCY1A2 | c.1962_1964del p.R655del | In Frame Del (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- KCNA7 | c.441_458del p.V148_I153del | In Frame Del (DEL) | VAF 12/68 reads (18%) | called by mutect2, pindel
- LRBA | c.7986_8013del p.D2663Mfs*22 | Frame Shift Del (DEL) | VAF 13/98 reads (13%) | called by mutect2, pindel
- MAGI3 | c.1858_1877del p.K620Cfs*21 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel, varscan2
- MYO10 | c.2594dup p.L865Ffs*9 | Frame Shift Ins (INS) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- PCDHB9 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- PRRC2B | c.3430_3445del p.L1144Gfs*21 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel, varscan2
- REXO4 | c.92dup p.N31Kfs*126 | Frame Shift Ins (INS) | VAF 61/243 reads (25%) | called by pindel, varscan2
- SHROOM4 | c.3287_3313del p.K1096_P1105delinsT | In Frame Del (DEL) | VAF 9/28 reads (32%) | called by mutect2, pindel
- SP1 | c.720_743del p.L241_G248del (on ENST00000327443 / NM_138473.3; = p.L234_G241del on NM_003109.1) | In Frame Del (DEL) | VAF 8/92 reads (9%) | called by mutect2, pindel
- SPATA32 | c.571_585del p.P191_A195del | In Frame Del (DEL) | VAF 10/72 reads (14%) | called by mutect2, pindel, varscan2
- ZNF592 | c.303_326del p.P102_K109del | In Frame Del (DEL) | VAF 14/36 reads (39%) | called by mutect2, pindel
- AC011455.2 | c.642G>A p.E214= | Silent (SNP) | VAF 31/53 reads (58%) | catalogued as COSV55500722; called by muse, mutect2, varscan2
- ACP3 | c.738C>T p.L246= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV60487596; called by muse, mutect2, varscan2
- ACSL6 | c.768A>G p.Q256= (on ENST00000379240; = p.Q281= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV57302562; called by muse, mutect2, varscan2
- ACVR2A | c.564T>C p.G188= | Silent (SNP) | VAF 77/111 reads (69%) | catalogued as COSV54026351; called by muse, mutect2, varscan2
- ADNP | c.2979A>G p.P993= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as COSV62426314; called by muse, mutect2, varscan2
- ADRM1 | c.382C>T p.L128= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV53351989, COSV53366612; called by muse, mutect2, varscan2
- AKNAD1 | c.1518C>T p.F506= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV62201477; called by muse, mutect2, varscan2
- ALKBH4 | c.225G>C p.L75= | Silent (SNP) | VAF 14/138 reads (10%) | catalogued as COSV52961554; called by muse, mutect2, varscan2
- ANK3 | c.1215T>C p.H405= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as COSV55071763; called by muse, mutect2
- AP1B1 | c.1665C>T p.I555= | Silent (SNP) | VAF 64/93 reads (69%) | catalogued as rs368718777; called by muse, mutect2, varscan2
- APCDD1 | c.168C>T p.L56= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs367556237, COSV62372717, COSV62372895; called by muse, mutect2, varscan2
- ATF6B | c.1101C>T p.L367= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV64352326; called by muse, mutect2, varscan2
- ATF7IP | c.3600T>G p.A1200= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV53774704; called by muse, mutect2, varscan2
- ATG2A | c.585G>T p.V195= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs867794167, COSV65967917; called by muse, mutect2, varscan2
- ATG2B | c.4110G>A p.Q1370= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV55891587; called by muse, mutect2, varscan2
- ATG4D | c.1164G>A p.K388= | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as COSV57265364; called by muse, mutect2, varscan2
- BANK1 | c.249G>A p.L83= | Silent (SNP) | VAF 46/97 reads (47%) | catalogued as COSV59846934; called by muse, mutect2, varscan2
- BAZ1A | c.375T>A p.I125= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV62411530; called by muse, mutect2, varscan2
- BRD3 | c.186C>G p.P62= | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as COSV57705354; called by muse, mutect2, varscan2
- BRI3BP | c.183C>T p.F61= | Silent (SNP) | VAF 16/21 reads (76%) | catalogued as rs761065540, COSV100413050; called by muse, varscan2
- BTN3A3 | c.1422C>T p.F474= | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as COSV55072934; called by muse, mutect2, varscan2
- BTRC | c.402G>A p.K134= (on ENST00000370187 / NM_033637.4; = p.K98= on NM_003939.5) | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV64561177, COSV64562466; called by muse, mutect2, varscan2
- C19orf47 | c.1212G>A p.Q404= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as COSV63510336; called by muse, mutect2, varscan2
- C1orf109 | c.81G>A p.L27= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV59239999; called by muse, mutect2, varscan2
- C5orf49 | c.180T>C p.F60= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV67709202; called by muse, mutect2, varscan2
- C7orf26 | c.438G>A p.V146= | Silent (SNP) | VAF 37/145 reads (26%) | catalogued as COSV60419696; called by muse, mutect2, varscan2
- CAPNS2 | c.384G>A p.V128= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as COSV50897667; called by muse, mutect2, varscan2
- CARD14 | c.753G>A p.L251= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as COSV60121616, COSV60125443; called by muse, mutect2, varscan2
- CARNS1 | c.2100T>C p.R700= | Silent (SNP) | VAF 27/116 reads (23%) | catalogued as COSV57052995; called by muse, mutect2, varscan2
- CCDC9 | c.75G>A p.R25= | Silent (SNP) | VAF 50/115 reads (43%) | catalogued as COSV55721890, COSV99699912; called by muse, mutect2, varscan2
- CDK5RAP3 | c.396G>A p.Q132= | Silent (SNP) | VAF 72/148 reads (49%) | catalogued as rs1453514553, COSV58115712; called by muse, mutect2, varscan2
- CEP55 | c.693A>G p.E231= | Silent (SNP) | VAF 30/43 reads (70%) | catalogued as rs1421426452, COSV65185541; called by muse, mutect2, varscan2
- CHKB | c.693T>C p.S231= | Silent (SNP) | VAF 104/155 reads (67%) | catalogued as COSV56418073; called by muse, mutect2, varscan2
- CLCN7 | c.402G>T p.G134= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as rs1208445815, COSV51972383; called by muse, mutect2, varscan2
- CMAS | c.732T>C p.H244= | Silent (SNP) | VAF 40/65 reads (62%) | catalogued as rs773481891, COSV57557167; called by muse, mutect2, varscan2
- COL1A1 | c.897T>A p.G299= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV56807935; called by muse, mutect2, varscan2
- CPNE3 | c.1272G>A p.L424= | Silent (SNP) | VAF 74/180 reads (41%) | catalogued as COSV52208682, COSV52210788; called by muse, mutect2, varscan2
- CR2 | c.255C>T p.F85= | Silent (SNP) | VAF 45/67 reads (67%) | catalogued as COSV65506047; called by muse, mutect2, varscan2
- CTSK | c.678G>A p.E226= | Silent (SNP) | VAF 16/183 reads (9%) | catalogued as COSV55013066; called by muse, mutect2
- CUX1 | c.3456C>T p.T1152= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV52908769; called by muse, mutect2, varscan2
- DCST1 | c.1248G>A p.Q416= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as COSV55061591; called by muse, mutect2, varscan2
- DIO2 | c.189C>T p.V63= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV70445826; called by muse, mutect2, varscan2
- DNAAF1 | c.2166G>A p.P722= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs764624773, COSV58987924; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAAF2 | c.651G>A p.P217= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs747603885, COSV100024114; called by muse, varscan2
- DNAJB1 | c.423C>T p.F141= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV54317631; called by muse, mutect2, varscan2
- DNAJC9 | c.486C>T p.I162= | Silent (SNP) | VAF 39/93 reads (42%) | catalogued as COSV54353384; called by muse, mutect2, varscan2
- DNMT1 | c.1620C>T p.L540= | Silent (SNP) | VAF 40/74 reads (54%) | catalogued as COSV61581873; called by muse, mutect2, varscan2
- DOCK9 | c.5871G>A p.K1957= (on ENST00000376460 / NM_001366676.2; = p.K1958= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV59621520, COSV59637712; called by muse, mutect2, varscan2
- DOP1A | c.7397G>A p.*2466= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV99382030; called by muse, mutect2
- DST | c.8877C>T p.F2959= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs1254572959, COSV55029737, COSV99751129; called by muse, mutect2, varscan2
- DUS1L | c.706C>T p.L236= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs764653880, COSV57650667; called by muse, mutect2, varscan2
- DUSP4 | c.120G>A p.P40= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV53544823; called by muse, mutect2, varscan2
- DYM | c.564C>T p.F188= | Silent (SNP) | VAF 47/89 reads (53%) | catalogued as rs755775980, COSV53989228; called by muse, mutect2, varscan2
- EDC4 | c.4170C>T p.L1390= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV59303394; called by muse, mutect2
- ERAP1 | c.777G>A p.K259= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV57085138, COSV57090055; called by muse, mutect2, varscan2
- FADD | c.330A>G p.K110= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV57229579; called by muse, mutect2, varscan2
- FAM241B | c.363G>A p.R121= | Silent (SNP) | VAF 18/140 reads (13%) | catalogued as rs745505897, COSV64768626; called by muse, mutect2, varscan2
- FAM71A | c.888G>A p.L296= | Silent (SNP) | VAF 28/35 reads (80%) | catalogued as COSV54236571, COSV54237437; called by muse, mutect2, varscan2
- FAXDC2 | c.768C>A p.I256= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs748985025, COSV58173432; called by muse, mutect2, varscan2
- FBXO41 | c.873G>T p.V291= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1254828252, COSV99721283; called by muse, mutect2
- FLOT2 | c.1227C>T p.L409= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as COSV67529292; called by muse, mutect2, varscan2
- FN1 | c.4563C>T p.V1521= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV60559224; called by muse, mutect2, varscan2
- FOXL2 | c.474G>A p.A158= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1192728328, COSV100374580; called by muse, varscan2
- FZD7 | c.1299C>T p.L433= | Silent (SNP) | VAF 42/73 reads (58%) | catalogued as rs1421612764, COSV53810956; called by muse, mutect2, varscan2
- GALNT8 | c.702G>A p.E234= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV52899748; called by muse, mutect2, varscan2
- GALNTL6 | c.9G>A p.R3= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV72553077, COSV72553176; called by muse, mutect2, varscan2
- GCLC | c.1395G>T p.L465= (on ENST00000643939; = p.L463= on NM_001498.4) | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV57596917; called by muse, mutect2
- GIMAP2 | c.801C>T p.I267= | Silent (SNP) | VAF 30/56 reads (54%) | catalogued as COSV56235946; called by muse, mutect2, varscan2
- GON7 | c.90C>T p.F30= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV50150636; called by muse, mutect2, varscan2
- GPHN | c.1077A>G p.V359= (on ENST00000315266 / NM_001377519.1; = p.V392= on NM_020806.5) | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs200461676, COSV59487602; called by muse, mutect2, varscan2
- GRIK4 | c.2787G>A p.Q929= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs1324520433, COSV101483624; called by muse, mutect2, varscan2
- GTPBP8 | c.132G>A p.L44= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV55607064; called by muse, mutect2, varscan2
- GYG1 | c.402C>A p.S134= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as COSV56049615, COSV56050689; called by muse, mutect2, varscan2
- HDAC7 | c.2578C>T p.L860= (on ENST00000427332; = p.L899= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs1340299951, COSV99316284; called by muse, mutect2, varscan2
- HNRNPA1 | c.90G>A p.L30= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs747731298, COSV52937987; called by muse, mutect2, varscan2
- HOMER3 | c.177C>T p.I59= | Silent (SNP) | VAF 36/136 reads (26%) | catalogued as COSV55355018, COSV55357893; called by muse, mutect2, varscan2
- HSD11B1L | c.420G>A p.V140= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV56797950; called by muse, mutect2, varscan2
- HSP90AA1 | c.1371G>A p.K457= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV53488300; called by muse, mutect2, varscan2
- INTS3 | c.1605C>T p.F535= | Silent (SNP) | VAF 36/61 reads (59%) | catalogued as rs1424942483, COSV59680195; called by muse, mutect2, varscan2
- INTU | c.1575G>A p.L525= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV58873526, COSV58875769; called by muse, mutect2
- IPO13 | c.318C>T p.F106= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV64894827; called by muse, mutect2, varscan2
- ITPRID2 | c.1492C>T p.L498= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV57474687; called by muse, mutect2, varscan2
- KCNA1 | c.921C>G p.R307= | Silent (SNP) | VAF 38/58 reads (66%) | catalogued as COSV66838237; called by muse, mutect2, varscan2
- KCNH1 | c.723C>T p.F241= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV55093757, COSV55098654; called by muse, mutect2, varscan2
- KEAP1 | c.663C>T p.F221= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV50537385; called by muse, mutect2, varscan2
- KIF3C | c.582G>A p.V194= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as COSV53100898; called by muse, mutect2, varscan2
- KIRREL3 | c.1179G>A p.A393= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs754793851, COSV69385668; called by muse, mutect2, varscan2
- KLF4 | c.693G>A p.L231= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as rs1254784268, COSV65929319; called by muse, mutect2
- KNL1 | c.4392T>C p.Y1464= (on ENST00000346991 / NM_170589.5; = p.Y1438= on NM_144508.5) | Silent (SNP) | VAF 34/59 reads (58%) | catalogued as COSV61158217; called by muse, mutect2, varscan2
- KTI12 | c.855G>A p.L285= | Silent (SNP) | VAF 25/173 reads (14%) | catalogued as COSV65406019; called by muse, mutect2, varscan2
- LHX1 | c.597C>T p.F199= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as rs1375807844; called by muse, mutect2, varscan2
- LRP1B | c.324C>T p.D108= | Silent (SNP) | VAF 39/66 reads (59%) | catalogued as rs766907792, COSV67194820, COSV67252815; called by muse, mutect2, varscan2
- LTBP1 | c.1164T>C p.H388= (on ENST00000404816 / NM_206943.4; = p.H62= on NM_000627.4) | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV100617253; called by muse, mutect2
- MACC1 | c.2397T>C p.Y799= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as COSV60545024; called by muse, mutect2
- MAP11 | c.1113G>A p.V371= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV57587554; called by muse, mutect2, varscan2
- MAST2 | c.1206G>A p.E402= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as COSV63620275; called by muse, mutect2
- MED13L | c.2016C>T p.L672= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs530164873, COSV56125844, COSV99929413; called by muse, varscan2
- MFSD8 | c.27A>G p.E9= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs1216544839, COSV56552160; called by muse, mutect2, varscan2
- MIOS | c.1779A>G p.A593= | Silent (SNP) | VAF 45/144 reads (31%) | catalogued as rs760076658, COSV60769888; called by muse, mutect2, varscan2
- MOGS | c.468C>T p.F156= | Silent (SNP) | VAF 35/111 reads (32%) | catalogued as COSV52028925, COSV99281164; called by muse, mutect2, varscan2
- MRM2 | c.444A>T p.A148= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV54248770; called by muse, mutect2, varscan2
- MUC17 | c.4791T>C p.P1597= | Silent (SNP) | VAF 118/295 reads (40%) | catalogued as COSV60297246; called by muse, mutect2, varscan2
- MX2 | c.1842C>T p.P614= | Silent (SNP) | VAF 8/87 reads (9%) | catalogued as rs1391466635, COSV58098155; called by muse, mutect2
- MYO3A | c.4617C>T p.F1539= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as COSV56341298; called by muse, mutect2, varscan2
- MZB1 | c.420C>T p.S140= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs1223215973, COSV56171859; called by muse, mutect2, varscan2
- NFKB2 | c.633A>G p.P211= | Silent (SNP) | VAF 93/192 reads (48%) | catalogued as COSV50052228; called by muse, mutect2, varscan2
- NLRP3 | c.903C>A p.G301= | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as COSV60228955; called by muse, mutect2, varscan2
- NOD2 | c.2043G>A p.L681= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs1202890376, COSV56053339; called by muse, mutect2, varscan2
- NOS1 | c.2433C>A p.T811= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV57617733; called by muse, mutect2, varscan2
- NPR2 | c.258C>T p.D86= | Silent (SNP) | VAF 49/163 reads (30%) | catalogued as COSV61313285; called by muse, mutect2, varscan2
- NTS | c.30A>G p.V10= | Silent (SNP) | VAF 50/106 reads (47%) | catalogued as COSV55456625; called by muse, mutect2, varscan2
- ODF3L1 | c.699A>G p.P233= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV59820379; called by muse, mutect2, varscan2
- OR10A6 | c.135T>C p.I45= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as COSV59165619; called by muse, mutect2, varscan2
- PC | c.1005C>T p.V335= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV63081886; called by muse, mutect2, varscan2
- PDE1C | c.63C>T p.I21= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs1455708832, COSV68815264; called by muse, mutect2, varscan2
- PDRG1 | c.132G>A p.L44= | Silent (SNP) | VAF 48/97 reads (49%) | catalogued as COSV52430986, COSV52431920; called by muse, mutect2, varscan2
- PFKFB4 | c.516G>A p.V172= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV51682119; called by muse, mutect2, varscan2
- PIP4K2A | c.762C>T p.V254= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV60540970; called by muse, mutect2, varscan2
- PKD1 | c.8355C>A p.G2785= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99238240; called by muse, mutect2, varscan2
- PMS1 | c.1920A>G p.E640= | Silent (SNP) | VAF 66/186 reads (35%) | catalogued as COSV59718828; called by muse, mutect2, varscan2
- PPARGC1A | c.1092C>T p.L364= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV53531405; called by muse, mutect2, varscan2
- PRKD3 | c.1848A>G p.Q616= | Silent (SNP) | VAF 55/138 reads (40%) | catalogued as COSV52215909; called by muse, mutect2, varscan2
- PRSS12 | c.2016C>T p.L672= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV56608427; called by muse, mutect2, varscan2
- PURA | c.849G>A p.E283= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV58762632; called by muse, mutect2, varscan2
- QSER1 | c.2679A>G p.S893= (on ENST00000399302; = p.S1022= on NM_001076786.3) | Silent (SNP) | VAF 50/76 reads (66%) | catalogued as rs368869898; called by muse, mutect2, varscan2
- RAB3A | c.318C>T p.N106= | Silent (SNP) | VAF 39/126 reads (31%) | catalogued as rs1221105793, COSV55852270; called by muse, mutect2, varscan2
- RABL6 | c.477C>T p.L159= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV61038485; called by muse, mutect2, varscan2
- RALBP1 | c.336C>T p.F112= | Silent (SNP) | VAF 32/58 reads (55%) | catalogued as rs1457368104, COSV50037302; called by muse, mutect2, varscan2
- REXO4 | c.141G>A p.K47= | Silent (SNP) | VAF 55/222 reads (25%) | catalogued as rs1554781971, COSV63022414; called by muse, varscan2
- RFX2 | c.2100C>T p.D700= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as rs1053405905, COSV57943924; called by muse, mutect2, varscan2
- RNF149 | c.1170G>A p.R390= | Silent (SNP) | VAF 51/65 reads (78%) | catalogued as rs773637702, COSV54864936; called by muse, mutect2, varscan2
- RPS6KA6 | c.1782T>C p.L594= | Silent (SNP) | VAF 75/111 reads (68%) | catalogued as COSV53123846; called by muse, mutect2, varscan2
- RUNX1T1 | c.633C>A p.L211= (on ENST00000265814 / NM_001198628.1; = p.L184= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV56146250, COSV56156423; called by muse, mutect2, varscan2
- RUSC1 | c.1452G>A p.K484= (on ENST00000368352 / NM_001105203.2; = p.K15= on NM_014328.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as COSV52741646; called by muse, mutect2, varscan2
- SCN11A | c.5007A>G p.V1669= | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as rs1415459152, COSV56574583; ClinVar: likely benign; called by muse, varscan2
- SEMA5B | c.1350G>A p.L450= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV52103939; called by muse, mutect2, varscan2
- SHD | c.697C>T p.L233= | Silent (SNP) | VAF 51/79 reads (65%) | catalogued as COSV73378762; called by muse, mutect2, varscan2
- SLC35D3 | c.96C>T p.L32= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV59378127; called by muse, mutect2, varscan2
- SLC35G2 | c.39A>G p.K13= | Silent (SNP) | VAF 36/146 reads (25%) | catalogued as COSV104431205, COSV67588744; called by muse, mutect2, varscan2
- SLC39A12 | c.1368T>C p.H456= | Silent (SNP) | VAF 39/87 reads (45%) | catalogued as rs773232109, COSV66201006; called by muse, mutect2, varscan2
- SLC44A4 | c.1182C>T p.I394= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV99998971; called by muse, mutect2
- SPEF1 | c.612G>A p.Q204= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs1309616156, COSV65729219; called by muse, mutect2, varscan2
- STARD7 | c.540C>T p.F180= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs539795637, COSV100474724; called by muse, varscan2
- STRIP1 | c.1218C>T p.P406= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs1049915270, COSV63929962; called by muse, mutect2, varscan2
- SWI5 | c.180T>C p.S60= | Silent (SNP) | VAF 62/145 reads (43%) | catalogued as COSV60792684; called by muse, mutect2, varscan2
- TANC2 | c.1776C>T p.F592= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV101267724, COSV67338421; called by muse, mutect2, varscan2
- TENM2 | c.2115G>A p.Q705= (on ENST00000518659 / NM_001122679.2; = p.Q473= on NM_001080428.3) | Silent (SNP) | VAF 34/42 reads (81%) | catalogued as rs1417335590, COSV69137030; called by muse, mutect2, varscan2
- TFAP2B | c.657G>C p.L219= | Silent (SNP) | VAF 63/188 reads (34%) | catalogued as rs963513478, COSV53829856; called by muse, mutect2, varscan2
- TFEC | c.162T>C p.D54= | Silent (SNP) | VAF 57/216 reads (26%) | catalogued as COSV55404359; called by muse, mutect2, varscan2
- THSD4 | c.2139G>C p.T713= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs764158675, COSV55978132, COSV99965114; called by muse, mutect2, varscan2
- TIMELESS | c.1278C>T p.R426= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV57513752; called by muse, mutect2, varscan2
- TMEM39B | c.390C>G p.T130= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV60380395; called by muse, mutect2, varscan2
- TMEM64 | c.732G>A p.L244= | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as COSV69128041; called by muse, mutect2, varscan2
- TRHDE | c.552T>C p.A184= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV53856477; called by muse, mutect2, varscan2
- TRIM38 | c.678C>T p.L226= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV62642644; called by muse, mutect2, varscan2
- TRMT10A | c.456G>A p.K152= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs371955245, COSV56745773; called by muse, mutect2, varscan2
- TSC22D4 | c.1062G>A p.R354= | Silent (SNP) | VAF 26/48 reads (54%) | catalogued as COSV55724163, COSV55724816; called by muse, mutect2, varscan2
- TTN | c.7149T>C p.S2383= (on ENST00000591111; = p.S2337= on NM_003319.4) | Silent (SNP) | VAF 29/125 reads (23%) | catalogued as COSV60222611; called by muse, mutect2, varscan2
- TTN | c.4863C>A p.V1621= (on ENST00000591111; = p.V1575= on NM_003319.4) | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as rs1490287801, COSV60222654; called by muse, mutect2, varscan2
- TULP4 | c.324G>A p.V108= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV65578759; called by muse, mutect2, varscan2
- USP25 | c.357G>A p.E119= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs780328219, COSV53487804; called by muse, mutect2, varscan2
- USP3 | c.594G>A p.G198= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV99165720; called by muse, mutect2, varscan2
- USP31 | c.1419T>C p.F473= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV54855002; called by muse, mutect2, varscan2
- VWA5A | c.1602T>A p.P534= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV64413790; called by muse, varscan2
- WDR46 | c.939G>A p.L313= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV65842721; called by muse, mutect2, varscan2
- ZC3H12C | c.735G>A p.L245= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV53708397; called by muse, mutect2
- ZNF398 | c.330G>A p.Q110= | Silent (SNP) | VAF 68/128 reads (53%) | catalogued as COSV60066133; called by muse, mutect2, varscan2
- ZNF506 | c.123C>T p.I41= | Silent (SNP) | VAF 69/170 reads (41%) | catalogued as COSV71354333, COSV71354546; called by muse, mutect2, varscan2
- ZNF507 | c.2034G>A p.A678= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as rs889356999, COSV61332567; called by muse, mutect2, varscan2
- ZNF512 | c.1200C>T p.I400= | Silent (SNP) | VAF 36/111 reads (32%) | catalogued as COSV62677279; called by muse, mutect2, varscan2
- ZNF571 | c.1737C>T p.I579= | Silent (SNP) | VAF 8/142 reads (6%) | catalogued as COSV60734234; called by muse, mutect2
- ZNF583 | c.729T>G p.V243= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as COSV99382144; called by muse, mutect2
- ZNF671 | c.117G>A p.A39= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs747594790, COSV58051842; called by muse, mutect2, varscan2
- ZNF777 | c.811C>A p.R271= | Silent (SNP) | VAF 19/175 reads (11%) | catalogued as COSV56099236, COSV56100861; called by muse, mutect2, varscan2
- ZNF782 | c.1293C>T p.F431= | Silent (SNP) | VAF 63/138 reads (46%) | catalogued as rs778943438, COSV56654160; called by muse, mutect2, varscan2
- ALDH3A2 | c.1443+1211T>A | Intron (SNP) | VAF 35/254 reads (14%) | catalogued as COSV51567968; called by muse, mutect2, varscan2
- ARMC5 | c.1864+59G>T | Intron (SNP) | VAF 8/38 reads (21%) | catalogued as rs1487572552, COSV51658645; called by muse, mutect2, varscan2
- CASZ1 | c.-2G>A | 5'UTR (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100681492; called by muse, mutect2, varscan2
- DCX | c.-22-530C>T | Intron (SNP) | VAF 43/66 reads (65%) | catalogued as COSV100576675, COSV57572923; called by muse, mutect2, varscan2
- ERCC6 | c.1397+6931C>G | Intron (SNP) | VAF 10/102 reads (10%) | catalogued as COSV63392758; called by muse, mutect2
- HAS3 | chr16:69118433 C>T | 3'Flank (SNP) | VAF 6/31 reads (19%) | catalogued as COSV54708387; called by muse, mutect2, varscan2
- JUN | c.-2C>T | 5'UTR (SNP) | VAF 13/111 reads (12%) | catalogued as rs756037775, COSV100973388, COSV100973431; called by muse, mutect2, varscan2
- LINC01600 | n.898C>T | RNA (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- MORF4 | n.345A>C | RNA (SNP) | VAF 16/121 reads (13%) | called by muse, mutect2, varscan2
- NOP56 | c.1159+97C>T | Intron (SNP) | VAF 8/50 reads (16%) | catalogued as rs1166170968, COSV100250134; called by muse, mutect2, varscan2
- RTL8C | c.-1G>A | 5'UTR (SNP) | VAF 20/29 reads (69%) | catalogued as rs1270380769, COSV57060238; called by muse, mutect2, varscan2
- SMC1A | c.109+524G>A | Intron (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2, varscan2
- SSPOP | n.2777C>G | RNA (SNP) | VAF 13/127 reads (10%) | catalogued as COSV50486280, COSV50487764; called by muse, mutect2
- SUCO | chr1:172532500 C>T | 5'Flank (SNP) | VAF 10/26 reads (38%) | catalogued as rs1405121397, COSV55268891, COSV55271963; called by muse, mutect2, varscan2
- SYTL2 | c.1459+2950A>G | Intron (SNP) | VAF 23/96 reads (24%) | catalogued as rs1479733965, COSV60361554; called by muse, mutect2, varscan2
- TBX2 | chr17:61412105 G>A | 3'Flank (SNP) | VAF 27/43 reads (63%) | catalogued as rs368263585; called by muse, mutect2, varscan2
- THRB | c.284-12595C>T | Intron (SNP) | VAF 9/65 reads (14%) | catalogued as COSV54979251; called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+1583G>A | Intron (SNP) | VAF 11/68 reads (16%) | catalogued as COSV100678582; called by muse, mutect2, varscan2
